TCGA case TCGA-08-0349 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: UCSF. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0645038d-8abe-4a79-8695-bf8824d33f67

Demographics
Sex at birth: male; Ethnicity: not hispanic or latino; Age at index: 46 years; Vital status: Dead; Days to death: 298 days.

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 46.4 years (16,964 days); Year of diagnosis: 2000; Method of diagnosis: Surgical Resection; Prior treatment: No.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 38 days; Days to treatment end: 85 days; Treatment dose: 5,940 cGy; Number of fractions: 33; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 38 days; Days to treatment end: 93 days; Number of cycles: 1; Treatment dose: 150 mg/m2/day; Route of administration: Oral.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Thalidomide; Treatment intent type: Adjuvant; Days to treatment start: 38 days; Days to treatment end: 93 days; Treatment dose: 200 mg/day.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carmustine; Initial disease status: Progressive Disease; Days to treatment start: 105 days; Days to treatment end: 183 days; Number of cycles: 2; Treatment dose: 480 mg; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fenretinide; Initial disease status: Progressive Disease; Days to treatment start: 231 days; Days to treatment end: 259 days; Number of cycles: 1; Treatment dose: 2,600 mg/day; Route of administration: Oral.
2. Progression of diagnosis 1 (Glioblastoma). Age at diagnosis: 46.7 years (17,057 days); Days to diagnosis: 93 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease.

Follow-up (3 entries)
- Day 93 (post initial treatment): Progression or recurrence: Yes; Days to progression: 93 days.
- Days to follow up: 231 days; Disease response: With Tumor.
- Days to follow up: 298 days; Disease response: With Tumor.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-08-0349-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 0.7; Intermediate dimension: 0.7; Shortest dimension: 0.5.
  Slide TCGA-08-0349-01A-01-TS1: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 15; Percent stromal cells: 10.
  Slide TCGA-08-0349-01A-01-BS1: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 10.
- Sample TCGA-08-0349-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-08-0349-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection.
- Drug treatment 2: Pharmaceutical therapy drug name: Temodar.
- Drug treatment 2, Route of administrations: Route of administration: PO.
- Drug treatment 3: Pharmaceutical therapy drug name: Bcnu.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 298 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 298 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 93 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-08-0349-01): tumor purity 0.8, ploidy 1.94, whole-genome doublings 0 (call status: snp_call).
